Somatic mutation profile of tumor specimen TCGA-RS-A6TO-01A (aliquot TCGA-RS-A6TO-01A-32D-A34J-08) from TCGA case TCGA-RS-A6TO, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, keratinizing, NOS; Tissue or organ of origin: Mouth, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G2; Age at diagnosis: 82.4 years (30,104 days).
Specimen TCGA-RS-A6TO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5d4344ee-35b1-4f34-ab05-711af623c8ba.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-RS-A6TO-10A (Blood Derived Normal), aliquot TCGA-RS-A6TO-10A-01D-A34M-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/bc2877a6-f07a-42b1-b72f-77be025eea6f

The open-access MAF lists 172 somatic variants for this specimen: 125 protein-altering or splice-affecting, 46 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 110, Silent 46, Nonsense Mutation 8, Splice Site 3, Frame Shift Del 2, Intron 1, Frame Shift Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.238C>T p.R80* | Nonsense Mutation (SNP) | VAF 15/26 reads (58%) | hotspot (GDC flag); catalogued as rs121913388, CM014695, COSV58682746, COSV58721651; ClinVar: risk factor / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 9/45 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 19/56 reads (34%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCA1 | c.3847C>T p.R1283C | Missense Mutation (SNP) | VAF 18/101 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as rs367658137; called by muse, mutect2, varscan2
- AHNAK2 | c.922C>T p.R308C | Missense Mutation (SNP) | VAF 11/28 reads (39%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.93); catalogued as rs779111209, COSV100317705; called by muse, mutect2, varscan2
- AKAP4 | c.2297C>G p.S766C | Missense Mutation (SNP) | VAF 5/29 reads (17%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.888); catalogued as COSV100654275; called by muse, mutect2, varscan2
- ANKS1B | c.1816G>T p.A606S | Missense Mutation (SNP) | VAF 10/240 reads (4%) | SIFT tolerated (0.95); PolyPhen probably damaging (0.978); catalogued as COSV100245891; called by muse, mutect2
- ANXA10 | c.188A>G p.Y63C | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT tolerated (0.07); PolyPhen benign (0.007); catalogued as COSV100829034; called by muse, mutect2, varscan2
- AP4E1 | c.3337C>G p.L1113V | Missense Mutation (SNP) | VAF 38/165 reads (23%) | SIFT tolerated (0.53); PolyPhen benign (0.416); catalogued as COSV99956706; called by muse, mutect2, varscan2
- ARHGAP9 | c.1790G>A p.R597H (on ENST00000393797 / NM_001319850.2; = p.R578H on NM_032496.4) | Missense Mutation (SNP) | VAF 21/68 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs376421872; called by muse, mutect2, varscan2
- ARL8A | c.394C>T p.R132* | Nonsense Mutation (SNP) | VAF 27/206 reads (13%) | catalogued as COSV99693293; called by muse, mutect2, varscan2
- ATG4D | c.508G>A p.E170K | Missense Mutation (SNP) | VAF 42/89 reads (47%) | SIFT tolerated (0.08); PolyPhen benign (0.027); catalogued as rs757684533, COSV58762274; called by muse, mutect2, varscan2
- ATP2B4 | c.613G>A p.E205K | Missense Mutation (SNP) | VAF 97/271 reads (36%) | SIFT deleterious (0.04); PolyPhen benign (0.159); catalogued as COSV100397555; called by muse, mutect2, varscan2
- ATP6AP2 | c.454C>T p.R152C | Missense Mutation (SNP) | VAF 29/210 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.683); catalogued as rs745734335, COSV65797833, COSV65798347; called by muse, mutect2, varscan2
- BAG5 | c.630T>G p.N210K | Missense Mutation (SNP) | VAF 37/134 reads (28%) | SIFT tolerated, low confidence (0.97); PolyPhen benign (0.001); catalogued as COSV99914876; called by muse, mutect2, varscan2
- BAZ2A | c.5191G>A p.E1731K | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.003); catalogued as COSV99466361; called by muse, mutect2, varscan2
- BIRC6 | c.13682C>T p.S4561F | Missense Mutation (SNP) | VAF 7/36 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV101428338; called by muse, mutect2, varscan2
- CACNG4 | c.620T>C p.I207T | Missense Mutation (SNP) | VAF 47/157 reads (30%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.844); catalogued as rs754169853, COSV100047622; called by muse, mutect2, varscan2
- CAND1 | c.913C>G p.L305V | Missense Mutation (SNP) | VAF 4/41 reads (10%) | SIFT tolerated (0.21); PolyPhen benign (0.015); catalogued as COSV101598276; called by muse, mutect2
- CCT5 | c.31G>A p.E11K | Missense Mutation (SNP) | VAF 13/93 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as COSV99725377; called by muse, mutect2
- CDCA2 | c.1526G>T p.R509I | Missense Mutation (SNP) | VAF 25/142 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV100398888; called by muse, mutect2, varscan2
- CELA3A | c.347C>T p.S116L | Missense Mutation (SNP) | VAF 22/170 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.009); catalogued as rs147890009; called by muse, varscan2
- CLVS1 | c.623G>A p.G208E | Missense Mutation (SNP) | VAF 51/121 reads (42%) | SIFT tolerated (0.08); PolyPhen benign (0.148); catalogued as COSV100370072; called by muse, mutect2, varscan2
- CNOT6L | c.1127T>C p.M376T (on ENST00000504123 / NM_001286790.2; = p.M371T on NM_144571.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.811); catalogued as COSV99361897; called by muse, mutect2, varscan2
- CNTN6 | c.919C>G p.L307V | Missense Mutation (SNP) | VAF 19/136 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.039); catalogued as COSV100610804; called by muse, mutect2, varscan2
- COX15 | c.1229A>C p.K410T | Missense Mutation (SNP) | VAF 8/55 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99187195; called by muse, mutect2, varscan2
- CPTP | c.176C>A p.S59Y | Missense Mutation (SNP) | VAF 16/73 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.361); catalogued as COSV100028373, COSV59562733; called by muse, mutect2, varscan2
- CREBBP | c.133A>G p.I45V | Missense Mutation (SNP) | VAF 18/117 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99270277; called by muse, mutect2, varscan2
- CXorf56 | c.355A>T p.T119S (on ENST00000536133 / NM_001170570.2; = p.T133S on NM_022101.4) | Missense Mutation (SNP) | VAF 46/306 reads (15%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV100233392; called by muse, mutect2, varscan2
- DAB1 | c.1267G>A p.V423I (on ENST00000371231; = p.V390I on NM_021080.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/72 reads (18%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs374160257, COSV64697791; called by muse, mutect2, varscan2
- DCAF12L1 | c.847G>A p.D283N | Missense Mutation (SNP) | VAF 10/106 reads (9%) | SIFT tolerated (0.42); PolyPhen probably damaging (0.996); catalogued as COSV100948322; called by muse, mutect2
- DENND1A | c.1299+1G>A p.X433_splice | Splice Site (SNP) | VAF 11/126 reads (9%) | catalogued as COSV65331507; called by muse, mutect2
- DNAH9 | c.12749C>T p.P4250L | Missense Mutation (SNP) | VAF 20/103 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99306109; called by muse, mutect2, varscan2
- DST | c.5567G>A p.R1856Q | Missense Mutation (SNP) | VAF 30/84 reads (36%) | SIFT tolerated (0.37); PolyPhen benign (0.406); catalogued as rs773685576, COSV54996130; called by muse, mutect2, varscan2
- ECEL1 | c.887G>A p.R296Q | Missense Mutation (SNP) | VAF 23/69 reads (33%) | SIFT tolerated (0.2); PolyPhen benign (0.036); catalogued as COSV58814134; called by muse, mutect2, varscan2
- ELL2 | c.1292C>G p.S431C | Missense Mutation (SNP) | VAF 88/179 reads (49%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV99427529; called by muse, mutect2, varscan2
- ESF1 | c.1522G>T p.E508* | Nonsense Mutation (SNP) | VAF 33/123 reads (27%) | catalogued as COSV99176379; called by muse, mutect2, varscan2
- FAM186B | c.1027G>C p.E343Q | Missense Mutation (SNP) | VAF 23/225 reads (10%) | SIFT tolerated (0.2); PolyPhen benign (0.243); catalogued as COSV99219139; called by muse, mutect2, varscan2
- FBXO4 | c.297G>C p.W99C | Missense Mutation (SNP) | VAF 29/137 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99715175; called by muse, mutect2, varscan2
- FCRL1 | c.1085C>T p.P362L | Missense Mutation (SNP) | VAF 6/35 reads (17%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.659); catalogued as COSV100839801, COSV63826569; called by muse, mutect2, varscan2
- FGF17 | c.491G>A p.R164H | Missense Mutation (SNP) | VAF 15/25 reads (60%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.982); catalogued as COSV100846155; called by muse, mutect2, varscan2
- FNIP1 | c.1300C>T p.R434C | Missense Mutation (SNP) | VAF 17/76 reads (22%) | SIFT deleterious (0.04); PolyPhen benign (0.222); catalogued as rs757970564, COSV57197421; called by muse, mutect2, varscan2
- FOLH1 | c.547G>A p.E183K | Missense Mutation (SNP) | VAF 15/142 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.112); catalogued as COSV57045475, COSV99923286, COSV99923733; called by muse, mutect2, varscan2
- FRA10AC1 | c.139G>A p.A47T | Missense Mutation (SNP) | VAF 25/95 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.033); catalogued as COSV100784712; called by muse, mutect2, varscan2
- GALNT10 | c.1720T>G p.F574V | Missense Mutation (SNP) | VAF 7/105 reads (7%) | SIFT tolerated (0.12); PolyPhen benign (0.359); catalogued as COSV99769217; called by muse, mutect2
- GRIP2 | c.796G>C p.D266H (on ENST00000619221; = p.D169H on NM_001080423.4) | Missense Mutation (SNP) | VAF 11/106 reads (10%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.952); catalogued as COSV99817371; called by muse, mutect2, varscan2
- H2BC21 | c.213C>G p.F71L | Missense Mutation (SNP) | VAF 29/224 reads (13%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.404); catalogued as COSV100479607, COSV58611455; called by muse, mutect2, varscan2
- HBD | c.17C>G p.P6R | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT tolerated (0.32); PolyPhen benign (0.247); catalogued as COSV99496719; called by muse, mutect2, varscan2
- HSPB2 | c.304C>T p.R102W | Missense Mutation (SNP) | VAF 12/90 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as rs782717759, COSV99909862; called by muse, mutect2, varscan2
- HTR3A | c.725C>G p.P242R | Missense Mutation (SNP) | VAF 19/113 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100248446; called by muse, mutect2, varscan2
- HUWE1 | c.7462G>C p.E2488Q | Missense Mutation (SNP) | VAF 5/91 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.063); catalogued as COSV99472586, COSV99472729; called by muse, mutect2
- IKBKB | c.1243C>T p.Q415* | Nonsense Mutation (SNP) | VAF 55/99 reads (56%) | catalogued as COSV100645711, COSV60597290; called by muse, mutect2, varscan2
- IKZF1 | c.1460G>A p.R487H | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.997); catalogued as COSV100498199, COSV100498439; called by muse, mutect2, varscan2
- IL17RC | c.1867C>T p.R623C (on ENST00000295981 / NM_153461.4; = p.R537C on NM_032732.6 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 5/22 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99925811; called by muse, mutect2, varscan2
- IPO7 | c.1993C>T p.Q665* | Nonsense Mutation (SNP) | VAF 17/95 reads (18%) | catalogued as COSV63352960; called by muse, mutect2, varscan2
- ITIH6 | c.382G>A p.E128K | Missense Mutation (SNP) | VAF 3/39 reads (8%) | SIFT tolerated (0.17); PolyPhen benign (0.18); catalogued as COSV99513389; called by muse, mutect2
- KLF17 | c.108G>C p.L36F | Missense Mutation (SNP) | VAF 49/126 reads (39%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.905); catalogued as COSV100954956; called by muse, mutect2, varscan2
- KMT2D | c.2141C>T p.S714L | Missense Mutation (SNP) | VAF 31/197 reads (16%) | SIFT tolerated, low confidence (0.63); PolyPhen benign (0); catalogued as rs747636808, COSV99982493; called by muse, mutect2, varscan2
- KNTC1 | c.3565G>A p.E1189K | Missense Mutation (SNP) | VAF 15/94 reads (16%) | SIFT tolerated (0.09); PolyPhen benign (0.017); catalogued as COSV100338386; called by muse, mutect2, varscan2
- LHX2 | c.566C>T p.A189V | Missense Mutation (SNP) | VAF 9/65 reads (14%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.939); catalogued as COSV65317956; called by muse, mutect2
- LRFN4 | c.557C>T p.P186L | Missense Mutation (SNP) | VAF 8/44 reads (18%) | SIFT deleterious (0.03); PolyPhen benign (0.066); catalogued as rs1465249592, COSV58923687; called by muse, mutect2
- LRP12 | c.2221C>T p.R741C | Missense Mutation (SNP) | VAF 38/116 reads (33%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.764); catalogued as rs141755380, COSV52632547; called by muse, mutect2, varscan2
- LRTM1 | c.618C>G p.D206E | Missense Mutation (SNP) | VAF 15/48 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV99836065; called by muse, mutect2, varscan2
- MAGEB1 | c.672G>A p.M224I | Missense Mutation (SNP) | VAF 13/56 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.105); catalogued as COSV100974990, COSV66776068; called by muse, mutect2, varscan2
- MAGEC2 | c.466T>C p.Y156H | Missense Mutation (SNP) | VAF 55/330 reads (17%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.994); catalogued as COSV99909638; called by muse, mutect2, varscan2
- MAGT1 | c.232T>A p.F78I (on ENST00000618282 / NM_001367916.1; = p.F110I on NM_032121.5) | Missense Mutation (SNP) | VAF 48/411 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.546); catalogued as COSV100800240; called by muse, mutect2, varscan2
- MCM3AP | c.5512G>A p.E1838K | Missense Mutation (SNP) | VAF 21/127 reads (17%) | SIFT tolerated (0.77); PolyPhen benign (0.04); catalogued as COSV99387016; called by muse, mutect2, varscan2
- MCM8 | c.1146G>C p.L382F | Missense Mutation (SNP) | VAF 17/155 reads (11%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as COSV99495712; called by muse, mutect2, varscan2
- MME | c.587G>C p.G196A | Missense Mutation (SNP) | VAF 16/110 reads (15%) | SIFT tolerated (0.18); PolyPhen possibly damaging (0.747); catalogued as COSV100852409; called by muse, mutect2, varscan2
- MSH4 | c.941C>T p.S314L | Missense Mutation (SNP) | VAF 20/71 reads (28%) | SIFT tolerated (0.23); PolyPhen benign (0.137); catalogued as COSV54202052; called by muse, mutect2, varscan2
- MUC16 | c.28502C>A p.A9501D | Missense Mutation (SNP) | VAF 30/194 reads (15%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.047); catalogued as COSV101200042; called by muse, mutect2, varscan2
- MYH10 | c.265G>A p.D89N | Missense Mutation (SNP) | VAF 43/206 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99345345; called by muse, mutect2, varscan2
- MYO1G | c.1499G>T p.R500L | Missense Mutation (SNP) | VAF 22/153 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as rs777044357, COSV51855409, COSV99348753; called by muse, mutect2, varscan2
- NBEA | c.3253G>C p.E1085Q | Missense Mutation (SNP) | VAF 10/25 reads (40%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); catalogued as COSV100080732; called by muse, mutect2, varscan2
- NEB | c.19327G>C p.E6443Q | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.64); catalogued as COSV99423796; called by muse, mutect2
- NELFE | c.830G>A p.R277H | Missense Mutation (SNP) | VAF 12/112 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.235); catalogued as rs1308688060, COSV100952769; called by muse, mutect2, varscan2
- NFE2L3 | c.784C>G p.L262V | Missense Mutation (SNP) | VAF 18/140 reads (13%) | SIFT tolerated (0.05); PolyPhen benign (0.048); catalogued as COSV99283748; called by muse, mutect2, varscan2
- NFE2L3 | c.859C>G p.L287V | Missense Mutation (SNP) | VAF 33/258 reads (13%) | SIFT tolerated (0.56); PolyPhen benign (0.025); catalogued as rs1311685925, COSV99283750; called by muse, mutect2, varscan2
- NFE2L3 | c.1465C>T p.L489F | Missense Mutation (SNP) | VAF 32/205 reads (16%) | SIFT tolerated (0.15); PolyPhen benign (0.011); catalogued as COSV99283752; called by muse, mutect2, varscan2
- NLRC5 | c.4667+1G>A p.X1556_splice | Splice Site (SNP) | VAF 33/77 reads (43%) | catalogued as COSV99347442; called by muse, mutect2, varscan2
- NLRP3 | c.1018C>A p.P340T | Missense Mutation (SNP) | VAF 42/112 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV100276155, COSV60220473; called by muse, mutect2, varscan2
- NRDC | c.1628C>G p.S543C | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100703439; called by muse, mutect2, varscan2
- OR2AK2 | c.845C>T p.T282I | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.393); catalogued as COSV100823769; called by muse, mutect2, varscan2
- PDZD4 | c.793G>A p.D265N | Missense Mutation (SNP) | VAF 24/76 reads (32%) | SIFT deleterious (0.02); PolyPhen benign (0); catalogued as rs782134205, COSV99381373; called by muse, mutect2, varscan2
- PLEKHS1 | c.1102A>G p.N368D | Missense Mutation (SNP) | VAF 7/42 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100613136; called by muse, mutect2, varscan2
- PPY | c.10G>A p.A4T | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT tolerated (0.52); PolyPhen benign (0); catalogued as rs756759648, COSV56823244; called by muse, mutect2
- PRKAB2 | c.244C>T p.R82C | Missense Mutation (SNP) | VAF 49/265 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs782281504, COSV99567957; called by muse, mutect2, varscan2
- PRMT5 | c.1054G>C p.E352Q | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.434); catalogued as COSV99363009; called by muse, mutect2
- PROKR1 | c.808G>C p.E270Q | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.574); catalogued as rs777297403, COSV100375559, COSV58136445; called by muse, mutect2, varscan2
- RAB35 | c.142C>T p.R48W | Missense Mutation (SNP) | VAF 35/76 reads (46%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1261521534, COSV57567915; called by muse, mutect2, varscan2
- REG3G | c.22C>G p.P8A | Missense Mutation (SNP) | VAF 10/61 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.015); catalogued as COSV55448847, COSV99709453; called by muse, mutect2, varscan2
- RSPRY1 | c.75G>T p.E25D | Missense Mutation (SNP) | VAF 16/198 reads (8%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.003); catalogued as COSV101071024; called by muse, mutect2
- SCIN | c.1345G>A p.E449K (on ENST00000297029 / NM_001112706.3; = p.E202K on NM_033128.3) | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs763690742, COSV99764901; called by muse, varscan2
- SEC14L1 | c.1116A>C p.E372D | Missense Mutation (SNP) | VAF 13/94 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.766); catalogued as COSV101171056; called by muse, mutect2, varscan2
- SETDB2 | c.1694G>C p.R565T | Missense Mutation (SNP) | VAF 24/156 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.254); catalogued as COSV99320788; called by muse, mutect2, varscan2
- SETX | c.5566G>T p.E1856* | Nonsense Mutation (SNP) | VAF 60/159 reads (38%) | catalogued as COSV56378682, COSV99809931; called by muse, mutect2, varscan2
- SLC10A5 | c.459G>C p.L153F | Missense Mutation (SNP) | VAF 36/173 reads (21%) | SIFT tolerated (0.13); PolyPhen benign (0.037); catalogued as rs1356554276, COSV101594257, COSV72828487; called by muse, mutect2, varscan2
- SLC12A8 | c.283G>A p.V95I | Missense Mutation (SNP) | VAF 21/56 reads (38%) | SIFT tolerated (0.52); PolyPhen benign (0.03); catalogued as rs945018902, COSV58868986; called by muse, mutect2, varscan2
- SLC5A4 | c.64C>G p.H22D | Missense Mutation (SNP) | VAF 46/244 reads (19%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as COSV99831940; called by muse, mutect2, varscan2
- SMCHD1 | c.706G>T p.G236C | Missense Mutation (SNP) | VAF 17/187 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99861800; called by muse, mutect2
- SORCS3 | c.2185C>T p.Q729* | Nonsense Mutation (SNP) | VAF 22/122 reads (18%) | catalogued as COSV100863576; called by muse, mutect2, varscan2
- SPOPL | c.661C>G p.R221G | Missense Mutation (SNP) | VAF 11/56 reads (20%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as COSV54515089, COSV99699513; called by muse, mutect2, varscan2
- STAT5A | c.1126G>A p.E376K | Missense Mutation (SNP) | VAF 16/117 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.948); catalogued as COSV100604618, COSV61808698; called by muse, varscan2
- TCP11L2 | c.1344G>T p.R448S | Missense Mutation (SNP) | VAF 17/67 reads (25%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100135376; called by muse, mutect2, varscan2
- TECTA | c.225C>G p.F75L | Missense Mutation (SNP) | VAF 5/46 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.956); catalogued as COSV99880041; called by muse, mutect2, varscan2
- TESK1 | c.1115G>A p.G372E | Missense Mutation (SNP) | VAF 22/132 reads (17%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.549); catalogued as COSV99427482; called by muse, mutect2, varscan2
- TNIP1 | c.1063G>A p.E355K | Missense Mutation (SNP) | VAF 8/53 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.79); catalogued as rs867041708, COSV100161309, COSV100161318; called by muse, mutect2, varscan2
- TRAF3IP1 | c.1408C>G p.R470G | Missense Mutation (SNP) | VAF 12/45 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100966897, COSV64852151; called by muse, mutect2, varscan2
- TRAK2 | c.2383C>G p.R795G | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.977); catalogued as COSV100216857; called by muse, mutect2, varscan2
- TRIM4 | c.1376_1378del p.F459del | In Frame Del (DEL) | VAF 43/199 reads (22%) | catalogued as rs1382015660; called by mutect2, pindel, varscan2
- TTN | c.81698G>C p.G27233A (on ENST00000591111; = p.G19809A on NM_003319.4) | Missense Mutation (SNP) | VAF 14/122 reads (11%) | PolyPhen probably damaging (0.996); catalogued as COSV100615592, COSV60069633; called by muse, mutect2, varscan2
- TXNDC16 | c.628C>T p.H210Y | Missense Mutation (SNP) | VAF 21/121 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.012); catalogued as rs764102813, COSV99909264; called by muse, mutect2, varscan2
- USP36 | c.2851G>A p.E951K | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated (0.25); PolyPhen benign (0.167); catalogued as COSV100361525; called by muse, mutect2, varscan2
- USP6NL | c.652C>A p.H218N | Missense Mutation (SNP) | VAF 23/141 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); catalogued as COSV99509693; called by muse, mutect2, varscan2
- WWP2 | c.227C>T p.T76M | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs375318503; called by muse, varscan2
- XAGE5 | c.35G>T p.R12L | Missense Mutation (SNP) | VAF 10/194 reads (5%) | SIFT tolerated (0.43); PolyPhen benign (0.341); catalogued as COSV100657823; called by muse, mutect2
- YDJC | c.59G>C p.R20P | Missense Mutation (SNP) | VAF 6/30 reads (20%) | SIFT tolerated (0.07); PolyPhen benign (0.071); catalogued as rs749004490, COSV99488941; called by muse, mutect2, varscan2
- ZC3H7A | c.682C>T p.H228Y | Missense Mutation (SNP) | VAF 17/103 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV63270488; called by muse, mutect2, varscan2
- ZKSCAN7 | c.810G>C p.L270F | Missense Mutation (SNP) | VAF 20/77 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV99837634; called by muse, mutect2, varscan2
- ZNF585B | c.463G>C p.E155Q | Missense Mutation (SNP) | VAF 19/564 reads (3%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.798); catalogued as COSV100459471, COSV57214598; called by muse, mutect2
- ZNF665 | c.241C>G p.Q81E (on ENST00000600412; = p.Q146E on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 29/197 reads (15%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.585); catalogued as rs1475538696, COSV101128431; called by muse, mutect2, varscan2
- CASP8 | c.411+2_411+5del p.X137_splice (on ENST00000432109 / NM_033355.3; = p.X169_splice on NM_001228.4) | Splice Site (DEL) | VAF 14/59 reads (24%) | called by mutect2, pindel, varscan2
- CNKSR2 | c.2902del p.E968Kfs*2 | Frame Shift Del (DEL) | VAF 36/145 reads (25%) | called by mutect2, pindel, varscan2
- FAT2 | c.12039_12057del p.H4014Gfs*15 | Frame Shift Del (DEL) | VAF 75/199 reads (38%) | called by mutect2, pindel, varscan2
- ZNF292 | c.4868dup p.N1625Kfs*5 | Frame Shift Ins (INS) | VAF 7/42 reads (17%) | called by mutect2, pindel, varscan2
- ADAM12 | c.1068C>T p.F356= | Silent (SNP) | VAF 17/81 reads (21%) | catalogued as rs778190289, COSV64106841; called by muse, mutect2, varscan2
- AL592490.1 | c.1789C>T p.L597= | Silent (SNP) | VAF 24/81 reads (30%) | catalogued as rs878906311, COSV101308212; called by muse, mutect2, varscan2
- AXIN1 | c.1680C>T p.S560= | Silent (SNP) | VAF 6/32 reads (19%) | catalogued as COSV99249878; called by muse, mutect2, varscan2
- BDH2 | c.129T>G p.L43= | Silent (SNP) | VAF 23/173 reads (13%) | catalogued as COSV99600712; called by muse, mutect2, varscan2
- CAPN13 | c.1452G>A p.L484= | Silent (SNP) | VAF 3/22 reads (14%) | catalogued as COSV99700288; called by muse, mutect2
- COL22A1 | c.1632C>T p.D544= | Silent (SNP) | VAF 34/111 reads (31%) | catalogued as rs373172764; called by muse, mutect2, varscan2
- COL25A1 | c.633C>T p.D211= | Silent (SNP) | VAF 12/118 reads (10%) | catalogued as COSV101211454; called by muse, mutect2, varscan2
- CREBBP | c.5601G>A p.R1867= | Silent (SNP) | VAF 13/87 reads (15%) | catalogued as COSV99270275; called by muse, mutect2, varscan2
- DOCK1 | c.2793C>T p.F931= | Silent (SNP) | VAF 7/38 reads (18%) | catalogued as rs548775401, COSV54731622; called by muse, mutect2, varscan2
- DPY19L1 | c.723G>A p.L241= | Silent (SNP) | VAF 17/63 reads (27%) | catalogued as COSV100204735; called by muse, mutect2, varscan2
- DUOXA2 | c.918G>A p.K306= | Silent (SNP) | VAF 23/112 reads (21%) | catalogued as COSV99973249; called by muse, mutect2, varscan2
- EGR2 | c.1398C>T p.L466= | Silent (SNP) | VAF 30/145 reads (21%) | catalogued as rs1483612429, COSV54346636; called by muse, mutect2, varscan2
- EPN3 | c.1617C>T p.F539= | Silent (SNP) | VAF 6/52 reads (12%) | catalogued as rs569447624, COSV99277012; called by mutect2, varscan2
- FBXO39 | c.987G>A p.L329= | Silent (SNP) | VAF 13/73 reads (18%) | catalogued as rs748574330, COSV100386209; called by muse, mutect2, varscan2
- GALC | c.1110C>T p.Y370= | Silent (SNP) | VAF 33/98 reads (34%) | catalogued as rs372793797, CM973367, CX162988; called by muse, mutect2, varscan2
- GPATCH8 | c.2241G>A p.R747= | Silent (SNP) | VAF 11/127 reads (9%) | catalogued as COSV100132686; called by muse, mutect2
- GRIN2B | c.4077C>T p.A1359= | Silent (SNP) | VAF 33/72 reads (46%) | catalogued as rs375217280, COSV101663059; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- HBM | c.72C>T p.F24= | Silent (SNP) | VAF 9/23 reads (39%) | catalogued as rs1472578127, COSV100720786; called by muse, mutect2, varscan2
- HSPA14 | c.394T>C p.L132= | Silent (SNP) | VAF 12/82 reads (15%) | catalogued as rs759789257, COSV101000672; called by muse, mutect2, varscan2
- ISCA1 | c.291A>G p.T97= | Silent (SNP) | VAF 33/319 reads (10%) | catalogued as rs760856594, COSV100276480; called by muse, mutect2, varscan2
- ITGAM | c.486C>T p.I162= | Silent (SNP) | VAF 33/236 reads (14%) | catalogued as COSV99792492; called by muse, mutect2, varscan2
- ITIH6 | c.717G>T p.G239= | Silent (SNP) | VAF 15/62 reads (24%) | catalogued as COSV99513387; called by muse, mutect2, varscan2
- KCNE3 | c.36G>A p.E12= | Silent (SNP) | VAF 11/74 reads (15%) | catalogued as COSV100035619; called by muse, mutect2, varscan2
- KIF3B | c.1095C>G p.L365= | Silent (SNP) | VAF 5/58 reads (9%) | catalogued as COSV100996388; called by muse, mutect2
- KRT2 | c.669C>A p.I223= | Silent (SNP) | VAF 26/257 reads (10%) | catalogued as COSV100548485, COSV59009478; called by muse, mutect2, varscan2
- LRIT1 | c.228C>A p.G76= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs762692802, COSV100928091, COSV64511914; called by muse, mutect2, varscan2
- MAGEC1 | c.1647T>A p.P549= | Silent (SNP) | VAF 47/417 reads (11%) | catalogued as COSV99595795; called by muse, mutect2, varscan2
- MYO5A | c.3123C>G p.L1041= | Silent (SNP) | VAF 15/76 reads (20%) | catalogued as COSV100697701; called by muse, mutect2, varscan2
- NFASC | c.2688C>T p.Y896= (on ENST00000339876 / NM_001378329.1; = p.Y999= on NM_015090.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 22/104 reads (21%) | catalogued as rs760083279, COSV100364032; called by muse, mutect2, varscan2
- PACS2 | c.1443C>G p.L481= | Silent (SNP) | VAF 45/283 reads (16%) | catalogued as COSV100330784; called by muse, mutect2, varscan2
- RAB41 | c.153C>T p.F51= (on ENST00000374473 / NM_001363807.1; = p.F50= on NM_001032726.3) | Silent (SNP) | VAF 15/88 reads (17%) | catalogued as COSV99333691; called by muse, mutect2, varscan2
- RPA1 | c.1446G>A p.P482= | Silent (SNP) | VAF 15/109 reads (14%) | catalogued as rs145553070; called by muse, mutect2, varscan2
- RPL32 | c.57G>A p.K19= | Silent (SNP) | VAF 89/348 reads (26%) | catalogued as COSV99832774; called by muse, mutect2, varscan2
- RUNX1T1 | c.912T>C p.D304= (on ENST00000265814 / NM_001198628.1; = p.D277= on NM_004349.4 and 1 other RefSeq transcript) | Silent (SNP) | VAF 100/231 reads (43%) | catalogued as COSV99752424; called by muse, mutect2, varscan2
- SCRIB | c.1092C>T p.D364= | Silent (SNP) | VAF 4/36 reads (11%) | catalogued as rs761055180, COSV57589174; called by muse, mutect2
- SERPINH1 | c.585G>A p.T195= | Silent (SNP) | VAF 9/58 reads (16%) | catalogued as rs1263785370, COSV100825027; called by muse, mutect2, varscan2
- SLC4A2 | c.2712G>A p.S904= | Silent (SNP) | VAF 9/87 reads (10%) | catalogued as rs763102759, COSV52539591; called by muse, mutect2
- SMARCD3 | c.504G>A p.A168= (on ENST00000262188 / NM_001003801.2; = p.A155= on NM_003078.4) | Silent (SNP) | VAF 68/208 reads (33%) | catalogued as rs200087546, COSV50388944, COSV50394123; called by muse, mutect2, varscan2
- SMG1 | c.4263C>A p.L1421= | Silent (SNP) | VAF 14/120 reads (12%) | catalogued as COSV101246102; called by muse, mutect2, varscan2
- SPI1 | c.39C>A p.V13= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as COSV57047809, COSV99908989; called by mutect2, varscan2
- TIGD3 | c.1338A>G p.E446= | Silent (SNP) | VAF 30/81 reads (37%) | catalogued as COSV99361701; called by muse, mutect2, varscan2
- TLR8 | c.2214G>A p.L738= (on ENST00000218032 / NM_138636.5; = p.L756= on NM_016610.4) | Silent (SNP) | VAF 25/215 reads (12%) | catalogued as COSV54319459, COSV99487043; called by muse, mutect2, varscan2
- TRIM6-TRIM34 | c.1557C>A p.I519= | Silent (SNP) | VAF 6/47 reads (13%) | catalogued as COSV100709049; called by muse, mutect2, varscan2
- TSNARE1 | c.936C>T p.S312= | Silent (SNP) | VAF 22/205 reads (11%) | catalogued as rs144275934; called by muse, mutect2, varscan2
- UBL7 | c.726C>T p.S242= | Silent (SNP) | VAF 6/40 reads (15%) | catalogued as rs1264552982, COSV100795402; called by muse, mutect2
- UBTF | c.174A>G p.V58= | Silent (SNP) | VAF 144/373 reads (39%) | catalogued as COSV100255964; called by muse, mutect2, varscan2
- MAP2 | c.5074-2096A>T | Intron (SNP) | VAF 7/63 reads (11%) | catalogued as rs911107549, COSV99560217; called by muse, mutect2, varscan2
